Somatic mutation profile of tumor specimen 0DNMAX from CCDI case PBCBDZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 17.0 years (6,225 days).
Specimen 0DNMAX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a7fc88b-a7e1-4953-b7e5-26a443bd0a63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNM9Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9112382f-713b-409e-abf0-874ae05c93d7

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 2, Nonsense Mutation 1, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 432/799 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- B3GNT2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 119/634 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs766045424, COSV57345249; called by muse, mutect2, varscan2
- DUOXA1 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 178/820 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146078577, COSV50993446; called by muse, mutect2, varscan2
- KIF4B | c.3439C>A p.P1147T | Missense Mutation (SNP) | VAF 343/1032 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV70528972; called by muse, mutect2, varscan2
- LRP1B | c.5829G>A p.W1943* | Nonsense Mutation (SNP) | VAF 675/1054 reads (64%) | catalogued as COSV67265336; called by muse, mutect2, varscan2
- USP15 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 274/456 reads (60%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs991384103; called by muse, mutect2, varscan2
- ZNF536 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 104/528 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138241491; called by muse, mutect2, varscan2
- ACER2 | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 309/771 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DENND1A | c.1196A>C p.K399T | Missense Mutation (SNP) | VAF 227/598 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- DGKA | c.1003_1006dup p.P336Lfs*12 | Frame Shift Ins (INS) | VAF 92/566 reads (16%) | called by mutect2, varscan2
- TRIP4 | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 147/631 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by mutect2, varscan2
- ULK3 | c.1288-5G>A | Splice Region (SNP) | VAF 58/391 reads (15%) | called by muse, mutect2, varscan2
- ZNF395 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 338/649 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTN3A1 | c.624G>T p.V208= | Silent (SNP) | VAF 102/519 reads (20%) | called by muse, mutect2, varscan2
- CHUK | c.651A>G p.G217= | Silent (SNP) | VAF 344/640 reads (54%) | catalogued as rs780603637; called by muse, mutect2, varscan2
- FLG | c.8901T>C p.H2967= | Silent (SNP) | VAF 72/580 reads (12%) | called by muse, mutect2, varscan2
- GM2A | c.177C>T p.I59= | Silent (SNP) | VAF 339/1088 reads (31%) | catalogued as rs745799277, COSV64095848; called by muse, mutect2
- KRTAP4-6 | c.93C>T p.C31= | Silent (SNP) | VAF 91/325 reads (28%) | called by muse, mutect2, varscan2
- UBE2O | c.396G>A p.K132= | Silent (SNP) | VAF 172/525 reads (33%) | called by muse, mutect2, varscan2
- CCL23 | c.302+25G>A | Intron (SNP) | VAF 88/707 reads (12%) | called by muse, mutect2, varscan2
- PCBP3 | c.675+538G>A | Intron (SNP) | VAF 35/219 reads (16%) | catalogued as rs1025126585; called by muse, mutect2, varscan2
- TTC6 | chr14:37792397 G>A | 5'Flank (SNP) | VAF 115/619 reads (19%) | called by muse, mutect2, varscan2
- ZNF771 | c.*81G>C | 3'UTR (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
